Gene-level copy-number profile of specimen HCM-BROD-0483-C16-85N from HCMI case HCM-BROD-0483-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 50.1 years (18,303 days).
Specimen HCM-BROD-0483-C16-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 673bc3a0-4e53-4abf-91b8-c4af42eeb49c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0483-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/943040fc-ff67-4a5f-83ed-274b7789bbfe

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,128; copy number 2: 15,739; copy number 3: 28,097; copy number 4: 9,274; copy number 5: 2,097; copy number 6: 442; copy number 7: 68; copy number 8: 92; copy number 9: 55; copy number 10: 1; copy number 11: 1; copy number 12: 340; copy number 13: 1; copy number 31: 12; copy number 36: 35; copy number 39: 2; copy number 44: 8.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 604 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:63,957,874–63,981,043, 2 genes, copy number 7: HTR1A, AC122707.1.
- chr7:79,768,028–80,226,181, 1 gene, copy number 12 (within-gene range 5–12): GNAI1.
- chr7:80,096,600–100,896,974, 351 genes, copy number 7–12 (broad region; genes not listed).
- chr7:107,808,734–108,721,601, 13 genes, copy number 13–31: PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1.
- chr7:116,275,606–117,883,675, 45 genes, copy number 36–44: AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1.
- chr10:23,694,746–24,723,887, 8 genes, copy number 8–9 (within-gene range 2–9): KIAA1217, NUP35P1, AC063961.1, MIR603, AL356113.1, AL353583.1, ARHGAP21, RNA5SP305.
- chr12:17,479,446–22,065,674, 59 genes, copy number 7 (within-gene range 4–7): AC048352.1, LINC02378, Y_RNA, RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS.
- chr15:20,531,856–20,541,800, 1 gene, copy number 7: GOLGA6L6.
- chr17:35,192,520–35,242,963, 2 genes, copy number 7: SLC35G3, AC022916.1.
- chr17:36,210,924–39,451,272, 118 genes, copy number 8–11 (broad region; genes not listed).
- chr17:39,687,914–39,747,291, 4 genes, copy number 8 (within-gene range 6–8): ERBB2, MIR4728, MIEN1, GRB7.

Autosomal genes at a single copy (total copy number 1): 2,128. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
